Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YG-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name:

Med. Rec. #:

DOB:

Gender:

Physician(s):

cc:

Client:

Location:

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Pelvic mass, bleeding, family history of ovarian cancer

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

Uterus, cervix, tubes and ovaries

ICD-O-3 Not applicable

Normal path from a non-cancer patient.
lw 11/11/11

DIAGNOSIS:

Uterus, cervix, tubes and ovaries:

Cervix:	Chronic cervicitis
Endometrium:	Proliferative endometrium
Myometrium:	Subserosal leiomyoma
Right ovary:	Ovarian tissue with physiologic changes
Right tube:	Unremarkable
Left ovary:	Ovarian tissue with physiologic changes
Left tube:	Unremarkable

Gross Description

Received in formalin labeled "uterus, cervix, bilateral ovaries and fallopian tubes" consists of a previously opened uterus with attached cervix and bilateral adnexa weighing 238 grams. The uterus overall measures 9.2 x 6.0 x 3.5 cm. The serosal surface is smooth and glistening, focally disrupted by a large subserosal fibroid measuring 6.5 x 4.5 x 4.0 cm. The cervix appears grossly unremarkable. The endometrium is pink-tan, smooth and measures up to 0.2 cm. Within the endometrium there is also a mucoid tan polypoid mass measuring up to 0.6 cm. The myometrium is tan and trabeculated and measures up to 1.3 cm. The left ovary measures 2.0 x 1.2 x 0.5 cm and appears tan yellow and cerebiform. Sectioning of the left ovary reveals a smooth, pink-tan surface with no gross lesions. The right tube measures 5.5 x 0.5 cm and is grossly unremarkable. The right ovary measures 2.0 x 1.0 x 0.8 cm and appears tan and cerebiform. Sectioning of the right ovary reveals a smooth tan and unremarkable surface. The left fallopian tube measures 7.0 x 1.0 cm and has attached fibrofatty tissue and a possible 1.0 cm paratubal cyst. The cut surface of the subserosal fibroid is pale-tan and whorled. There are no areas of hemorrhage or necrosis. Representative sections are submitted as follows:

KEY TO CASSETTES:

1	-	Cervix and endocervix
2-3	-	Endometrium, myometrium
4-7	-	Subserosal fibroid
8	-	Right adnexa

Revisions Statement:

This laboratory statement may be applicable to some of the reagent materials used in analyzing the above specimen. This test was developed and is performed in a laboratory that is not certified by the U.S. Food and Drug Administration. The FDA has determined that such laboratory is approved to not necessary. This test is used for clinical purposes. It should not be used for diagnostic or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity testing.

[page 2 of 2]
[REDACTED] **Surgical Pathology Report** [REDACTED]

9 - Left adnexa

Microscopic Description

The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file aec72394-ff55-4f47-acd1-20934e8560eb (TCGA-FL-A1YG.5E88F0A0-6949-485D-89BA-9769A8847919.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).